Gene-level copy-number profile of tumor specimen C3N-02435-01 from CPTAC case C3N-02435, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.4 years (23,531 days).
Specimen C3N-02435-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 08577563-b647-4aa8-b90c-4fb0837de4f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02435-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/98388ffa-735f-40c1-932b-08d76acdfc75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 21,169; copy number 2: 32,188; copy number 3: 3,561; copy number 4: 426; copy number 5: 780; copy number 7: 56; copy number 8: 17; copy number 10: 15; copy number 11: 46.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:48,440,352–48,467,645, 3 genes (within-gene range 0–1): AC134772.1, ATRIP, TREX1.
- chr5:180,967,189–181,007,384, 5 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P.
- chr9:12,134–110,138, 8 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1.
- chr9:19,789,179–24,592,104, 85 genes (broad region; genes not listed).
- chr9:25,088,811–26,118,408, 5 genes: RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,666,386, 4 genes: FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 914 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr9:64,765,054–64,765,535, 1 gene, copy number 8: IGKV1OR-2.
- chr10:9,721,963–15,073,853, 95 genes, copy number 5–11 (broad region; genes not listed).
- chr10:25,924,448–29,318,328, 67 genes, copy number 5–8 (broad region; genes not listed).
- chr11:69,641,156–70,436,584, 27 genes, copy number 5–7: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:66,251,745–67,670,919, 19 genes, copy number 5 (within-gene range 4–5): AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1.
- chr12:69,212,108–70,243,379, 26 genes, copy number 5 (within-gene range 4–5): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2.

Autosomal genes at a single copy (total copy number 1): 19,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
